Somatic mutation profile of tumor specimen C3N-01522-02 (aliquot CPT0077120009) from CPTAC case C3N-01522, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G2; Age at diagnosis: 80.4 years (29,350 days).
Specimen C3N-01522-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 3e83d04b-83fc-402b-a72f-3656392b43f7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-01522-71 (Blood Derived Normal), aliquot CPT0077230002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/493dd71c-7f5a-470a-83ac-18adc1563205

The open-access MAF lists 117 somatic variants for this specimen: 74 protein-altering or splice-affecting, 26 silent, 17 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 50, Silent 26, Intron 11, Frame Shift Del 10, Nonsense Mutation 9, 3'UTR 3, Splice Site 3, RNA 2, 5'UTR 1, Translation Start Site 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL035460.1 | c.184C>G p.Q62E | Missense Mutation (SNP) | VAF 12/52 reads (23%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.003); catalogued as COSV100730132; called by muse, mutect2
- APC | c.3203C>T p.S1068L | Missense Mutation (SNP) | VAF 84/284 reads (30%) | SIFT tolerated, low confidence (0.28); PolyPhen benign (0.024); catalogued as CD160909, CM023010, COSV57330367, COSV57359180; called by muse, mutect2, varscan2
- CKAP5 | c.2719G>T p.G907C | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.739); catalogued as COSV56367654; called by muse, mutect2, varscan2
- CTAGE1 | c.613C>T p.Q205* | Nonsense Mutation (SNP) | VAF 58/292 reads (20%) | catalogued as COSV101194675; called by muse, mutect2, varscan2
- CYP26A1 | c.941C>T p.T314I | Missense Mutation (SNP) | VAF 27/91 reads (30%) | SIFT tolerated (0.07); PolyPhen benign (0.006); catalogued as rs754813478; called by muse, mutect2, varscan2
- GAS2L2 | c.992G>A p.R331Q | Missense Mutation (SNP) | VAF 24/80 reads (30%) | SIFT tolerated (0.06); PolyPhen benign (0.081); catalogued as rs370992265; called by muse, mutect2, varscan2
- GBP3 | c.806C>T p.S269F | Missense Mutation (SNP) | VAF 62/189 reads (33%) | SIFT deleterious (0.04); PolyPhen benign (0.432); catalogued as COSV52519257; called by muse, mutect2, varscan2
- GRIN2A | c.251C>G p.T84R | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.684); catalogued as COSV58046734; called by muse, mutect2
- HECW1 | c.3937G>T p.G1313* | Nonsense Mutation (SNP) | VAF 99/229 reads (43%) | catalogued as COSV67835255; called by muse, mutect2, varscan2
- KDM5C | c.994C>T p.R332* | Nonsense Mutation (SNP) | VAF 42/138 reads (30%) | catalogued as CM061210, COSV64763470; called by muse, mutect2, varscan2
- KIAA2013 | c.422T>G p.V141G | Missense Mutation (SNP) | VAF 62/265 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.096); catalogued as rs1307752691; called by muse, mutect2, varscan2
- LRP1 | c.2309G>A p.R770Q | Missense Mutation (SNP) | VAF 198/576 reads (34%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs769851229, COSV54507646; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MAGEC3 | c.1813A>G p.M605V | Missense Mutation (SNP) | VAF 43/60 reads (72%) | SIFT deleterious (0.01); PolyPhen benign (0.034); catalogued as rs200784001; called by muse, mutect2, varscan2
- MMP17 | c.1636C>T p.P546S | Missense Mutation (SNP) | VAF 40/119 reads (34%) | SIFT deleterious (0.03); PolyPhen benign (0.038); catalogued as rs769408097, COSV100861946; called by muse, mutect2, varscan2
- MROH2A | c.2306C>G p.P769R | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1025990760; called by muse, mutect2, varscan2
- MROH5 | c.2095C>T p.Q699* | Nonsense Mutation (SNP) | VAF 34/117 reads (29%) | catalogued as rs1385014722; called by muse, mutect2, varscan2
- OR5J2 | c.331G>T p.E111* | Nonsense Mutation (SNP) | VAF 53/159 reads (33%) | catalogued as COSV100399225; called by muse, mutect2, varscan2
- PBRM1 | c.673A>T p.K225* | Nonsense Mutation (SNP) | VAF 27/73 reads (37%) | catalogued as COSV56277528; called by muse, mutect2, varscan2
- PCDHGB4 | c.922G>A p.E308K | Missense Mutation (SNP) | VAF 21/214 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs759041753, COSV99542639; called by muse, mutect2, varscan2
- PDGFRA | c.282C>A p.H94Q | Missense Mutation (SNP) | VAF 50/226 reads (22%) | SIFT tolerated (0.19); PolyPhen benign (0.081); catalogued as rs750282565, COSV57265306; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- PITPNM3 | c.1186G>T p.D396Y | Missense Mutation (SNP) | VAF 138/422 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs373601000; called by muse, mutect2, varscan2
- PLA2G7 | c.382A>G p.M128V | Missense Mutation (SNP) | VAF 88/311 reads (28%) | SIFT tolerated (0.94); PolyPhen benign (0); catalogued as rs928438839; called by muse, mutect2, varscan2
- PLEKHG3 | c.2977G>T p.D993Y (on ENST00000394691; = p.D1049Y on NM_001308147.2) | Missense Mutation (SNP) | VAF 42/190 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs777484347; called by muse, mutect2, varscan2
- PPWD1 | c.337G>T p.V113F | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.519); catalogued as COSV54333546; called by muse, mutect2
- RBBP9 | c.2T>C p.M1? | Translation Start Site (SNP) | VAF 57/207 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.073); catalogued as rs775738842; called by muse, mutect2, varscan2
- SLITRK6 | c.2135G>A p.S712N | Missense Mutation (SNP) | VAF 35/120 reads (29%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as rs1438568169; called by muse, mutect2, varscan2
- SPTBN2 | c.6343G>A p.G2115S | Missense Mutation (SNP) | VAF 159/495 reads (32%) | SIFT tolerated (0.9); PolyPhen benign (0.003); catalogued as rs200435710; called by muse, mutect2, varscan2
- SYNPO2 | c.361C>T p.R121* | Nonsense Mutation (SNP) | VAF 23/104 reads (22%) | catalogued as COSV61113779; called by mutect2, varscan2
- TEDDM1 | c.819del p.*274Efs*37 | Frame Shift Del (DEL) | VAF 23/69 reads (33%) | catalogued as rs759664603; called by mutect2, pindel, varscan2
- TMEM108 | c.166A>G p.S56G | Missense Mutation (SNP) | VAF 52/182 reads (29%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.306); catalogued as rs1303009645; called by muse, mutect2, varscan2
- ZNF98 | c.1510C>A p.H504N | Missense Mutation (SNP) | VAF 37/326 reads (11%) | SIFT tolerated (0.45); PolyPhen benign (0.005); catalogued as COSV63334597; called by muse, mutect2, varscan2
- ABCC3 | c.1635+1G>A p.X545_splice | Splice Site (SNP) | VAF 85/274 reads (31%) | called by muse, mutect2, varscan2
- ACAT2 | c.235A>T p.I79F | Missense Mutation (SNP) | VAF 10/126 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); called by muse, mutect2
- ADGRF1 | c.307T>C p.C103R | Missense Mutation (SNP) | VAF 29/87 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- AMPH | c.932del p.P311Rfs*24 | Frame Shift Del (DEL) | VAF 52/304 reads (17%) | called by mutect2, pindel, varscan2
- ATP13A1 | c.3416C>A p.A1139E | Missense Mutation (SNP) | VAF 52/184 reads (28%) | SIFT tolerated (0.06); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- C5orf24 | c.365del p.P122Qfs*46 | Frame Shift Del (DEL) | VAF 91/362 reads (25%) | called by mutect2, pindel, varscan2
- CCL24 | c.110T>G p.F37C | Missense Mutation (SNP) | VAF 16/132 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CEACAM21 | c.227_245del p.N76Mfs*2 | Frame Shift Del (DEL) | VAF 60/370 reads (16%) | called by mutect2, pindel, varscan2
- CHD6 | c.2629T>C p.F877L | Missense Mutation (SNP) | VAF 48/151 reads (32%) | SIFT deleterious (0); PolyPhen benign (0.371); called by muse, mutect2, varscan2
- CILP2 | c.978G>T p.W326C | Missense Mutation (SNP) | VAF 36/118 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CMBL | c.467-1G>C p.X156_splice | Splice Site (SNP) | VAF 32/95 reads (34%) | called by muse, mutect2, varscan2
- CYYR1 | c.146C>A p.S49Y | Missense Mutation (SNP) | VAF 46/135 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- ENTHD1 | c.1609G>T p.D537Y | Missense Mutation (SNP) | VAF 15/129 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.254); called by muse, mutect2, varscan2
- EXOC2 | c.50A>C p.E17A | Missense Mutation (SNP) | VAF 31/119 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- FAM227A | c.1129C>A p.H377N | Missense Mutation (SNP) | VAF 26/87 reads (30%) | SIFT tolerated (0.21); PolyPhen benign (0); called by muse, mutect2, varscan2
- GFPT2 | c.1278G>C p.E426D | Missense Mutation (SNP) | VAF 38/124 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); called by muse, mutect2, varscan2
- KDM5C | c.1610T>A p.V537E | Missense Mutation (SNP) | VAF 34/178 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL30 | c.1587C>A p.Y529* | Nonsense Mutation (SNP) | VAF 118/432 reads (27%) | called by muse, mutect2, varscan2
- LMO7 | c.4657C>G p.P1553A (on ENST00000357063; = p.P1234A on NM_005358.5) | Missense Mutation (SNP) | VAF 92/216 reads (43%) | SIFT tolerated (0.08); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- MPND | c.1048A>G p.S350G | Missense Mutation (SNP) | VAF 86/210 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MTRF1 | c.815T>C p.M272T | Missense Mutation (SNP) | VAF 65/179 reads (36%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.702); called by muse, mutect2, varscan2
- MYMK | c.509T>G p.F170C | Missense Mutation (SNP) | VAF 17/79 reads (22%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- NAALADL1 | c.2174_2175del p.T725Sfs*14 | Frame Shift Del (DEL) | VAF 31/119 reads (26%) | called by mutect2, pindel, varscan2
- NEB | c.4348A>T p.I1450F | Missense Mutation (SNP) | VAF 60/186 reads (32%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.964); called by muse, mutect2, varscan2
- NSD1 | c.2204C>A p.A735E | Missense Mutation (SNP) | VAF 92/335 reads (27%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR52H1 | c.423G>C p.K141N (on ENST00000322653; = p.K147N on NM_001005289.1) | Missense Mutation (SNP) | VAF 61/179 reads (34%) | SIFT tolerated (0.07); PolyPhen benign (0.131); called by muse, mutect2, varscan2
- PAFAH2 | c.584T>C p.V195A | Missense Mutation (SNP) | VAF 34/133 reads (26%) | SIFT tolerated (1); PolyPhen benign (0.228); called by muse, mutect2, varscan2
- PCED1A | c.821C>G p.P274R | Missense Mutation (SNP) | VAF 64/216 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by mutect2, varscan2
- PER3 | c.2295del p.N766Tfs*83 | Frame Shift Del (DEL) | VAF 49/213 reads (23%) | called by mutect2, pindel, varscan2
- PRR33 | c.64G>T p.G22* | Nonsense Mutation (SNP) | VAF 74/209 reads (35%) | called by muse, mutect2, varscan2
- RBL2 | c.602T>G p.F201C | Missense Mutation (SNP) | VAF 39/168 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- RIC8A | c.1065+2T>C p.X355_splice | Splice Site (SNP) | VAF 79/267 reads (30%) | called by muse, mutect2, varscan2
- ROCK2 | c.3176A>C p.K1059T | Missense Mutation (SNP) | VAF 38/153 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- SETD2 | c.887del p.S296Lfs*5 | Frame Shift Del (DEL) | VAF 9/44 reads (20%) | called by mutect2, pindel
- SLC22A12 | c.1045del p.R349Gfs*52 | Frame Shift Del (DEL) | VAF 129/482 reads (27%) | called by mutect2, pindel, varscan2
- SLCO1C1 | c.1888T>G p.C630G | Missense Mutation (SNP) | VAF 63/201 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SUGP1 | c.1853A>T p.E618V | Missense Mutation (SNP) | VAF 50/284 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TCEA2 | c.800dup p.N268Efs*13 | Frame Shift Ins (INS) | VAF 24/120 reads (20%) | called by mutect2, pindel, varscan2
- TDRD12 | c.296A>T p.K99M | Missense Mutation (SNP) | VAF 62/175 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); called by muse, mutect2, varscan2
- TMTC1 | c.2228T>A p.I743N (on ENST00000539277 / NM_001193451.2; = p.I635N on NM_175861.3) | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.941); called by muse, mutect2
- TRIM49D1 | c.1027del p.W343Gfs*67 | Frame Shift Del (DEL) | VAF 28/262 reads (11%) | called by mutect2, pindel, varscan2
- TRPV5 | c.1592T>A p.F531Y | Missense Mutation (SNP) | VAF 100/237 reads (42%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.761); called by muse, mutect2, varscan2
- ZXDC | c.2546del p.G849Efs*24 | Frame Shift Del (DEL) | VAF 57/267 reads (21%) | called by mutect2, pindel, varscan2
- ANKRD23 | c.489G>A p.L163= | Silent (SNP) | VAF 26/237 reads (11%) | called by muse, mutect2, varscan2
- ATP11B | c.1230T>C p.G410= | Silent (SNP) | VAF 32/123 reads (26%) | called by muse, mutect2
- CLCA4 | c.546C>T p.I182= | Silent (SNP) | VAF 10/105 reads (10%) | catalogued as rs370625612; called by muse, mutect2, varscan2
- DCUN1D2 | c.291T>A p.P97= | Silent (SNP) | VAF 75/248 reads (30%) | called by muse, mutect2, varscan2
- EMSY | c.153A>G p.E51= | Silent (SNP) | VAF 22/67 reads (33%) | called by muse, mutect2
- FNIP2 | c.1905G>A p.G635= | Silent (SNP) | VAF 32/133 reads (24%) | called by muse, mutect2, varscan2
- HNRNPF | c.273C>T p.T91= | Silent (SNP) | VAF 17/115 reads (15%) | catalogued as rs899239899, COSV61560762; called by muse, mutect2, varscan2
- HOMER2 | c.1059T>C p.D353= (on ENST00000304231 / NM_199330.3; = p.D342= on NM_004839.4) | Silent (SNP) | VAF 8/84 reads (10%) | called by muse, mutect2
- IFT172 | c.4383G>A p.Q1461= | Silent (SNP) | VAF 51/186 reads (27%) | catalogued as COSV53137617; called by muse, mutect2, varscan2
- ITLN1 | c.105A>C p.P35= | Silent (SNP) | VAF 45/181 reads (25%) | called by muse, mutect2, varscan2
- KMT2C | c.13371C>T p.G4457= | Silent (SNP) | VAF 11/182 reads (6%) | catalogued as rs1367219669; called by muse, mutect2
- LIPA | c.171T>C p.D57= | Silent (SNP) | VAF 25/159 reads (16%) | called by muse, mutect2, varscan2
- NCCRP1 | c.54G>A p.G18= | Silent (SNP) | VAF 127/418 reads (30%) | catalogued as rs753673551; called by muse, mutect2, varscan2
- OR2V1 | c.801G>C p.R267= | Silent (SNP) | VAF 22/88 reads (25%) | called by muse, mutect2, varscan2
- OR2Z1 | c.312C>A p.L104= | Silent (SNP) | VAF 63/211 reads (30%) | catalogued as COSV100136454; called by muse, mutect2, varscan2
- OR52K1 | c.486C>A p.P162= | Silent (SNP) | VAF 21/248 reads (8%) | called by muse, mutect2
- ORMDL2 | c.129C>T p.F43= | Silent (SNP) | VAF 29/121 reads (24%) | called by muse, mutect2, varscan2
- PRR14 | c.1272A>G p.P424= | Silent (SNP) | VAF 22/216 reads (10%) | called by muse, mutect2
- RAET1E | c.198T>C p.S66= | Silent (SNP) | VAF 20/155 reads (13%) | called by muse, mutect2, varscan2
- SLC25A30 | c.627C>G p.T209= | Silent (SNP) | VAF 28/93 reads (30%) | called by muse, mutect2, varscan2
- SNX11 | c.18G>A p.R6= | Silent (SNP) | VAF 57/169 reads (34%) | catalogued as rs772748470; called by muse, mutect2, varscan2
- TRIM15 | c.654C>T p.A218= | Silent (SNP) | VAF 16/200 reads (8%) | called by muse, mutect2
- TTN | c.48192A>G p.V16064= (on ENST00000591111; = p.V8640= on NM_003319.4) | Silent (SNP) | VAF 126/429 reads (29%) | catalogued as rs1182402471; called by muse, mutect2, varscan2
- UGCG | c.795A>G p.S265= | Silent (SNP) | VAF 33/135 reads (24%) | catalogued as rs757865261; called by muse, mutect2, varscan2
- ZNF343 | c.1621A>C p.R541= | Silent (SNP) | VAF 85/252 reads (34%) | catalogued as rs769462325; called by muse, mutect2, varscan2
- ZXDA | c.2115G>A p.L705= | Silent (SNP) | VAF 23/111 reads (21%) | called by muse, varscan2
- AKR1B1P6 | n.131C>A | RNA (SNP) | VAF 26/235 reads (11%) | called by muse, mutect2, varscan2
- APTX | c.-149G>A | 5'UTR (SNP) | VAF 78/348 reads (22%) | catalogued as rs564001060; called by muse, mutect2, varscan2
- COLEC11 | c.*67A>T | 3'UTR (SNP) | VAF 103/302 reads (34%) | called by muse, mutect2, varscan2
- CSNK1D | c.737-51T>A | Intron (SNP) | VAF 90/295 reads (31%) | called by muse, mutect2, varscan2
- DUX4L8 | n.740C>T | RNA (SNP) | VAF 24/470 reads (5%) | catalogued as rs782293950; called by muse, mutect2
- GTPBP8 | c.336+194C>T | Intron (SNP) | VAF 50/136 reads (37%) | called by muse, mutect2, varscan2
- IGFN1 | c.1242-540C>T | Intron (SNP) | VAF 45/283 reads (16%) | catalogued as rs944465078; called by muse, mutect2, varscan2
- KIAA0100 | c.516-16T>A | Intron (SNP) | VAF 32/83 reads (39%) | called by muse, mutect2, varscan2
- MTHFR | c.475+9C>A | Intron (SNP) | VAF 68/259 reads (26%) | called by muse, mutect2, varscan2
- MTPN | c.*2197A>T | 3'UTR (SNP) | VAF 33/98 reads (34%) | called by muse, mutect2, varscan2
- NOL3 | c.-8-245G>A | Intron (SNP) | VAF 65/168 reads (39%) | called by muse, mutect2, varscan2
- PAX1 | c.287-123G>A | Intron (SNP) | VAF 26/401 reads (6%) | catalogued as rs753261433; called by muse, mutect2
- PDE4DIP | c.*52A>T | 3'UTR (SNP) | VAF 89/333 reads (27%) | called by muse, mutect2, varscan2
- PDE6B | c.1060-39G>A | Intron (SNP) | VAF 20/208 reads (10%) | catalogued as rs369121532; called by muse, mutect2
- PHF20 | c.1826-154G>T | Intron (SNP) | VAF 13/169 reads (8%) | called by muse, mutect2
- RNF213 | c.11568+51C>G | Intron (SNP) | VAF 17/310 reads (5%) | called by muse, mutect2
- ZNF8 | c.66+535T>C | Intron (SNP) | VAF 68/353 reads (19%) | called by muse, mutect2, varscan2
